Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A7U6, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A7U6-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3

Carcinoma, clear cell 8310/3

Site: G Kidney NOS C64.9

QW 5/16/14

Diagnosis:

A: Perinephric fat, removal

- Benign fibroadipose tissue, negative for malignancy.

B: Renal mass, left, partial nephrectomy

Histologic tumor type/subtype: renal cell carcinoma,
conventional clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 3 (of 4)

Tumor size (greatest dimension): 2.9 cm maximum tumor size by
gross examination

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or
microscopic):

Capsular invasion/perirenal adipose tissue: negative

Gerota's fascia: not applicable

Renal sinus: not applicable

Major veins (renal vein or segmental branches, IVC): not
applicable

Ureter: not applicable

Venous (large vessel): negative

Lymphatic (small vessel): negative

Histologic assessment of surgical margins:

Renal parenchymal margin: negative

Renal capsular margin: negative

Perinephric adipose tissue margin: negative

Adrenal gland: not submitted

Lymph nodes: none identified

Pathologic findings in non-neoplastic kidney: mild
arteriolonephrosclerosis and interstitial chronic inflammation

[page 2 of 2]
AJCC Pathologic TNM Stage: pT1a pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

·year-old female with left renal mass.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "perinephric fat." It holds a 2.7 x 2.4 x

0.9 cm aggregate of soft yellow/tan, focally cauterized fat. No nodules or masses are identified. The specimen is entirely submitted in blocks A1 and A2.

Container B is additionally labeled "left renal mass." It holds a 17.1 gram, 4.2

x 4.0 x 2.0 cm partial nephrectomy. The capsule is inked blue, and the

parenchymal margin is inked black. Sectioning reveals a 2.9 x 2.4 x 2.3 cm

circumscribed variegated orange/red cortical mass expanding the capsule. This

mass comes within 0.2 cm of the closest parenchymal margin. The adjacent

cortical tissue is tan/brown and grossly unremarkable.

Representative sections

are submitted in blocks B1-B4.

Source: NCI Genomic Data Commons file 961d8413-fbfc-4cc6-8a11-085fbe7723dc (TCGA-B8-A7U6.27B82B1D-9142-4A49-9C30-5D052D216233.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).